Somatic mutation profile of tumor specimen TCGA-06-5859-01A (aliquot TCGA-06-5859-01A-01D-1696-08) from TCGA case TCGA-06-5859, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.5 years (23,211 days).
Specimen TCGA-06-5859-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 537fd586-8e22-4980-a94a-c72912bba108.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5859-10A (Blood Derived Normal), aliquot TCGA-06-5859-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06dd167b-3334-453e-a63f-dcd0f2c2e22a

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Frame Shift Del 3, Splice Region 1, Nonsense Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59328972; called by muse, mutect2, varscan2
- ADAMTS19 | c.2590G>A p.V864I | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as rs149851287; called by muse, mutect2, varscan2
- BCL11A | c.1522G>A p.A508T (on ENST00000335712 / NM_001365609.1; = p.A542T on NM_018014.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59627719; called by muse, mutect2, varscan2
- C12orf40 | c.234G>C p.M78I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV61131034; called by muse, mutect2, varscan2
- CACNA1S | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs146696298; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CARD11 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV62717095; called by muse, mutect2, varscan2
- CCDC85A | c.1452G>A p.P484= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as rs965236564, COSV68149492; called by muse, mutect2, varscan2
- DNAH17 | c.2812G>A p.V938I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs778684573, COSV101101543; called by muse, varscan2
- DOCK5 | c.1679C>A p.T560N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52399105; called by muse, mutect2, varscan2
- FAM47A | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV60495697; called by muse, mutect2, varscan2
- FRAS1 | c.4828G>A p.G1610S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV53602665; called by muse, mutect2
- KLHL6 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 64/145 reads (44%) | catalogued as rs772971768, COSV58065586, COSV58068837; called by muse, mutect2, varscan2
- L1CAM | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1557090439, COSV62827607; called by muse, mutect2, varscan2
- LHX3 | c.293C>T p.P98L (on ENST00000371748 / NM_178138.6; = p.P103L on NM_014564.5) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV65581561; called by muse, mutect2, varscan2
- MSLN | c.1495G>A p.E499K (on ENST00000382862 / NM_013404.4; = p.E491K on NM_005823.6) | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs747503528, COSV53500865; called by muse, mutect2, varscan2
- NCCRP1 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 188/502 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs772826705, COSV59212405; called by muse, mutect2, varscan2
- NCOA6 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV62862681; called by muse, mutect2, varscan2
- NIBAN1 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV62284218; called by muse, mutect2, varscan2
- OPLAH | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.756); catalogued as rs560233274, COSV70677705; called by muse, mutect2, varscan2
- OSBPL2 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.271); catalogued as rs746311450, COSV58216087; called by muse, mutect2, varscan2
- PDS5A | c.2666G>A p.R889Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57824527; called by muse, mutect2, varscan2
- PIWIL3 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59994683; called by muse, mutect2, varscan2
- PKDREJ | c.3646G>A p.G1216R | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53548425; called by muse, mutect2, varscan2
- PPL | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs142355114; called by muse, mutect2, varscan2
- PPME1 | c.157A>T p.M53L | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV60296253; called by muse, mutect2, varscan2
- SGPP2 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV58328089; called by muse, mutect2, varscan2
- SPATA31A3 | c.2762G>T p.R921M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1255321210; called by mutect2, varscan2
- SPO11 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs780860543, COSV61995397, COSV61996886; called by muse, mutect2, varscan2
- STRIP2 | c.1776+1G>A p.X592_splice | Splice Site (SNP) | VAF 45/164 reads (27%) | catalogued as rs1318760636, COSV50803810; called by muse, mutect2, varscan2
- TAS2R60 | c.17T>C p.M6T | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60330561; called by muse, mutect2, varscan2
- TCEA1 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV67172341; called by muse, mutect2, varscan2
- TEX15 | c.6196G>A p.V2066I (on ENST00000256246; = p.V2449I on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as rs753475065, COSV56344726; called by muse, mutect2, varscan2
- TLE4 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764833101, COSV54629140; called by muse, mutect2, varscan2
- TRIML1 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.387); catalogued as rs147254109; called by muse, mutect2, varscan2
- ZNF526 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV55898917; called by muse, mutect2, varscan2
- CLECL1 | c.224del p.L75* | Frame Shift Del (DEL) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- KLHL12 | c.1560del p.R521Dfs*14 | Frame Shift Del (DEL) | VAF 52/158 reads (33%) | called by mutect2, pindel, varscan2
- NPRL2 | c.116_117del p.T39Sfs*51 | Frame Shift Del (DEL) | VAF 48/129 reads (37%) | called by pindel, varscan2
- ACTN4 | c.2433C>T p.F811= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV53144881, COSV53150121; called by muse, mutect2, varscan2
- DNAH5 | c.10230G>A p.T3410= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs765000004, COSV54201418; called by muse, mutect2, varscan2
- EPHA8 | c.435C>T p.I145= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs142515766; called by muse, mutect2, varscan2
- HERPUD2 | c.171G>A p.V57= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV60944611; called by muse, mutect2, varscan2
- LHFPL4 | c.171C>A p.G57= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV55001705; called by muse, mutect2, varscan2
- OCLN | c.384C>T p.Y128= | Silent (SNP) | VAF 66/149 reads (44%) | catalogued as rs150730577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2A7 | c.204C>T p.V68= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs764358983, COSV101512182; called by muse, varscan2
- P2RY8 | c.966C>T p.R322= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as rs756454808, COSV67177069; called by muse, mutect2, varscan2
- SRCAP | c.891G>A p.E297= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs760370639, COSV52670459; called by muse, mutect2, varscan2
- TICRR | c.4923C>T p.T1641= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV51540320, COSV99176103; called by muse, mutect2, varscan2
- SSPOP | n.9957C>T | RNA (SNP) | VAF 21/93 reads (23%) | catalogued as rs139588484, COSV65128802; called by muse, mutect2, varscan2
